Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A1EF, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A1EF-01A (Primary Tumor).

[page 1 of 6]
Patient Key:
Surgical date:

ICD-O-3
Carcinoma, hepato-
cellular, NOS 8170/3
Site Code: Liver C22.0
1/19/11
fw

TISSUE DESCRIPTION:

A1 A. Right Lobe, Liver Routine Biopsy: 2 pieces, ranging from 2.0 cm in length x 0.1 cm in diameter to 2.2 cm in length x 0.1 cm in diameter

DIAGNOSIS:

Liver, right lobe, needle biopsy: Mildly active (grade 1 of 3) steatohepatitis with mild portal and periportal fibrosis (stage 1-2 of 4) (see comment).

DIAGNOSIS COMMENT:

The liver needle biopsy is adequate with more than 15 portal tracts. Each portal tract contains intact hepatic artery, bile duct, and portal vein branches. Mild focal lymphocytic infiltrate is also present in some of the portal tracts. No interface hepatitis is present. Mild portal and periportal fibrosis is present on the trichrome and reticulin stains. Liver parenchyma shows mild to moderate macrovesicular steatosis, focal hepatocellular ballooning, and mild lymphocytic aggregate. No hemosiderosis is present on the iron stain. No cytoplasmic globules are present on the PAS-d stain.

REVISED REPORT (Addendum/Procedure included)

TISSUE DESCRIPTION:

A1 A2 A3 A4 A5 A6 A7 A8 A9 A10 B1
Portion of left lateral liver (6.2 x 3.8 x 3.5 cm), tissue from superior margin of liver (1.8 x 1.0 x 0.8 cm).

DIAGNOSIS:

Liver, left lateral, resection: Grade 3 (of 4) hepatocellular carcinoma, forming a single 5.5 x 3.3 x 3.3 cm multinodular mass. The hepatic capsule is free of tumor. The surgical margins are free of tumor, the clearance being 0.3 cm microscopically. Extramural vascular invasion is not identified. The tumor is partially encapsulated, infiltration of parenchyma being of the pushing type. The non-neoplastic liver will be assessed on permanent sections and an addendum will be issued. Liver, superior margin, re-excision: Negative for tumor.

ADDENDUM:

Review of the permanent sections of adjacent nonneoplastic liver demonstrates a mild simple steatosis as manifested by

[page 2 of 6]
macrovesicular steatosis present in the zone 3 region. Scattered clusters of neutrophils are identified and are consistent with surgical hepatitis. The portal areas demonstrate a mixed chronic inflammatory cell infiltration that is relatively nonspecific. The interlobular bile ducts are intact and show no significant cellular injury. A mild degree of ductular proliferation is identified and is most likely due to mass effect of the adjacent hepatocellular carcinoma. Significant fibrosis is not identified. Please refer to the accompanying liver biopsy (medical liver biopsy, . for specific morphologic findings.

Review of the permanent sections of the tumor and adjacent nonneoplastic liver demonstrate focal venous invasion by the hepatocellular carcinoma.

[page 3 of 6]
Patient Key: .
Surgical date:

TISSUE DESCRIPTION:

A1 A. Right Lobe, Liver Routine Biopsy: 2 pieces, ranging from 2.0 cm in length x 0.1 cm in diameter to 2.2 cm in length x 0.1 cm in diameter

DIAGNOSIS:

Liver, right lobe, needle biopsy: Mildly active (grade 1 of 3) steatohepatitis with mild portal and periportal fibrosis (stage 1-2 of 4) (see comment).

DIAGNOSIS COMMENT:

The liver needle biopsy is adequate with more than 15 portal tracts. Each portal tract contains intact hepatic artery, bile duct, and portal vein branches. Mild focal lymphocytic infiltrate is also present in some of the portal tracts. No interface hepatitis is present. Mild portal and periportal fibrosis is present on the trichrome and reticulin stains. Liver parenchyma shows mild to moderate macrovesicular steatosis, focal hepatocellular ballooning, and mild lymphocytic aggregate. No hemosiderosis is present on the iron stain. No cytoplasmic globules are present on the PAS-d stain.

REVISED REPORT (Addendum/Procedure included)

TISSUE DESCRIPTION:

A1 A2 A3 A4 A5 A6 A7 A8 A9 A10 B1
Portion of left lateral liver (6.2 x 3.8 x 3.5 cm), tissue from superior margin of liver (1.8 x 1.0 x 0.8 cm).

DIAGNOSIS:

Liver, left lateral, resection: Grade 3 (of 4) hepatocellular carcinoma, forming a single 5.5 x 3.3 x 3.3 cm multinodular mass. The hepatic capsule is free of tumor. The surgical margins are free of tumor, the clearance being 0.3 cm microscopically. Extramural vascular invasion is not identified. The tumor is partially encapsulated, infiltration of parenchyma being of the pushing type. The non-neoplastic liver will be assessed on permanent sections and an addendum will be issued. Liver, superior margin, re-excision: Negative for tumor.

ADDENDUM:

Review of the permanent sections of adjacent nonneoplastic liver demonstrates a mild simple steatosis as manifested by

[page 4 of 6]
Patient Key: '

macrovesicular steatosis present in the zone 3 region. Scattered clusters of neutrophils are identified and are consistent with surgical hepatitis. The portal areas demonstrate a mixed chronic inflammatory cell infiltration that is relatively nonspecific. The interlobular bile ducts and intact and show no significant cellular injury. A mild degree of ductular proliferation is identified and is most likely due to mass affect of the adjacent hepatocellular carcinoma. Significant fibrosis is not identified. Please refer to the accompanying liver biopsy (medical liver biopsy, for specific morphologic findings.

Review of the permanent sections of the tumor and adjacent nonneoplastic liver demonstrate focal venous invasion by the hepatocellular carcinoma.

[page 5 of 6]
Patient Key:

Liver • Digestive System CAP Approved

* Data elements *with asterisks* are *not required* for accreditation purposes for the Commission on Cancer. These elements may be clinically important, but are not yet validated or regularly used in patient management. Alternatively, the necessary data may not be available to the pathologist at the time of pathologic assessment of this specimen.

LIVER: Resection

Patient name: (to be de-identified)

Surgical pathology number:

MACROSCOPIC

Specimen Type

- ☐ Right lobectomy
- ☐ Extended right lobectomy
- ☐ Medial segmentectomy
- ☒ Left lateral segmentectomy
- ☐ Total left lobectomy
- ☐ Explanted liver
- ☐ Other (specify): _____
- ☐ Not specified

Focality

- ☒ Solitary (specify location): left lateral
- ☐ Multiple (specify location): _____

Tumor Size

Greatest dimension: 4.5 cm

*Additional dimensions: 2.2 x 2.2 cm

☐ Cannot be determined (see Comment)

MICROSCOPIC

Histologic Type

- ☒ Hepatocellular carcinoma
- ☐ Fibrolamellar hepatocellular carcinoma variant (specify): _____
- ☐ Combined hepatocellular and cholangiocarcinoma
- ☐ Cholangiocarcinoma, intrahepatic
- ☐ Bile duct cystadenocarcinoma
- ☐ Undifferentiated carcinoma
- ☐ Other (specify): _____
- ☐ Carcinoma, type cannot be determined

Histologic Grade

- ☐ Not applicable
- ☐ GX: Cannot be assessed
- ☐ GI: Well differentiated
- ☐ GII: Moderately differentiated
- ☒ GIII: Poorly differentiated
- ☐ GIV: Undifferentiated/anaplastic
- ☐ Other (specify): _____

[page 6 of 6]
Pathologic Staging (pTNM)

Primary Tumor (pT)

- ☐ pTX: Cannot be assessed
☐ pT0: No evidence of primary tumor
☐ pT1: Solitary tumor with no vascular invasion
☒ pT2: Solitary tumor with vascular invasion or multiple tumors none more than 5 cm
☐ pT3: Multiple tumors more than 5 cm or tumor involving a major branch of the portal or hepatic vein(s)
☐ pT4: Tumor(s) with direct invasion of adjacent organs other than the gallbladder or perforation of visceral peritoneum

Regional Lymph Nodes (pN)

- ☒ pNX: Cannot be assessed
☐ pN0: No regional lymph node metastasis
☐ pN1: Regional lymph node metastasis

Specify: Number examined: ____

Number involved: ____

Distant Metastasis (pM)

- ☒ pMX: Cannot be assessed
☐ pM1: Distant metastasis

*Specify site(s), if known: _____

Margins (check all that apply)

Parenchymal Margin

- ☒ Cannot be assessed
☒ Uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 3.0 mm
Specify margin: _____

☐ Involved by invasive carcinoma

Bile Duct Margin (Cholangiocarcinoma Only)

- ☒ Cannot be assessed
☐ Uninvolved by invasive carcinoma
* ☐ Carcinoma in situ absent
* ☐ Carcinoma in situ present
☐ Involved by invasive carcinoma

Other Margin

Specify margin: _____

- ☐ Cannot be assessed
☐ Uninvolved by invasive carcinoma
☐ Involved by invasive carcinoma

***Venous (Large Vessel) Invasion (V)**

- * ☐ Absent
* ☒ Present
* ☒ Indeterminate

***Additional Pathologic Findings (check all that apply)**

- * ☐ None identified
* ☐ Hepatocellular dysplasia
* ☐ Ductal dysplasia
* ☐ Cirrhosis/fibrosis
* ☐ Iron overload

* ☐ Hepatitis (specify type): _____

* ☒ Other (specify): Mildly active Steatohepatitis

to mild portal and periductal fibrosis
associated hepatitis

Source: NCI Genomic Data Commons file 09422b6f-9581-41ff-a467-eae844e66512 (TCGA-DD-A1EF.002B24F9-22DB-4504-A048-BF9790A4837E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).